Somatic mutation profile of tumor specimen TARGET-30-PASSWB-01A (aliquot TARGET-30-PASSWB-01A-01D) from TARGET case TARGET-30-PASSWB, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 2.5 years (910 days).
Specimen TARGET-30-PASSWB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fee0a4d5-e058-4118-8dab-aaf7c40f3123.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASSWB-10A (Blood Derived Normal), aliquot TARGET-30-PASSWB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/497b8941-d3b8-48b7-8afe-f012f335b3d6

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 7, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSS3 | c.1013C>A p.A338E | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs766634948, COSV54097265; called by muse, mutect2, varscan2
- HOXA11 | c.893A>C p.K298T | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50054376; called by muse, mutect2, varscan2
- IER5 | c.319G>C p.V107L | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.5); PolyPhen benign (0.295); catalogued as COSV62537217; called by muse, varscan2
- IL36G | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV52079241, COSV99381268; called by muse, mutect2, varscan2
- KIAA1109 | c.2738C>T p.A913V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52689584; called by muse, mutect2, varscan2
- TMC1 | c.927C>A p.N309K | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.165); catalogued as COSV52783910; called by muse, mutect2, varscan2
- LILRA1 | c.421G>T p.V141L | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.432); called by muse, mutect2
- SAMD9 | c.3255C>A p.C1085* | Nonsense Mutation (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- CACNA1S | c.4467G>A p.E1489= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as rs1293597531; called by muse, mutect2
- FZD5 | c.835C>T p.L279= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1346633752, COSV54944550; called by muse, mutect2
- NKD2 | c.1011C>T p.S337= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs376860908; called by muse, mutect2, varscan2
- PIWIL4 | c.1815C>T p.G605= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs897919549, COSV100133077; called by muse, mutect2, varscan2
- SLC22A15 | c.183C>T p.H61= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs748295058, COSV65678906; called by muse, mutect2, varscan2
